FM case AD13694 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas.
https://portal.gdc.cancer.gov/cases/aa1ed8a4-398e-4bb2-aab0-9d5702e2b862

Female, 60.6 years: Adenocarcinoma, NOS (ICD-O-3 8140/3); specimen biopsied or resected from the pleura. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
